Somatic mutation profile of tumor specimen MMRF_1906_1_BM_CD138pos (aliquot MMRF_1906_1_BM_CD138pos_T1_KBS5U_L06426) from MMRF case MMRF_1906, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.2 years (28,215 days).
Specimen MMRF_1906_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b70fcc5-42dc-4873-96ca-62484f2f4a53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1906_2_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1906_2_PB_CD3pos_C1_KBS5U_L06458; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/092ea0c6-4a87-4bca-b6f8-f27232a73ac8

The open-access MAF lists 67 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 25, Missense Mutation 17, Intron 9, Silent 6, 5'Flank 4, Nonsense Mutation 2, RNA 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AK8 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100050602; called by muse, mutect2, varscan2
- FKBP1C | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs746685019; called by muse, mutect2, varscan2
- NCAPD3 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs1289567537; called by muse, mutect2, varscan2
- PHLDB2 | c.3119G>A p.R1040K (on ENST00000393925 / NM_001134439.2; = p.R997K on NM_145753.2) | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.443); catalogued as COSV67310841, COSV67311605; called by muse, mutect2, varscan2
- RARS1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as rs1348859672, COSV51565036; called by muse, mutect2
- SEC24A | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs1164635693; called by muse, mutect2, varscan2
- SIGLEC8 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100367111; called by muse, mutect2
- TATDN1 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765096907; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs778292073; called by muse, mutect2, varscan2
- CSMD3 | c.5107G>A p.D1703N (on ENST00000297405 / NM_001363185.1; = p.D1599N on NM_052900.3) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- GUCA2A | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- KIF11 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MED12 | c.216C>A p.N72K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.379); called by muse, mutect2
- PCDHA12 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PUS1 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2
- SAMSN1 | c.51A>C p.K17N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SMARCA2 | c.4471G>A p.D1491N | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- XPO4 | c.1889T>C p.L630P | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF804B | c.3135T>G p.D1045E | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF10L | c.249C>A p.P83= | Silent (SNP) | VAF 10/87 reads (11%) | called by mutect2, varscan2
- ITGB4 | c.2514G>A p.R838= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99564555; called by muse, mutect2, varscan2
- MUC4 | c.6249C>T p.V2083= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs774234711; called by muse, varscan2
- NSG2 | c.45G>A p.P15= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as rs202053280, COSV57458742; called by muse, mutect2, varscan2
- SUPT6H | c.1230A>G p.K410= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- UGT2B7 | c.1164C>T p.I388= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV100535215; called by muse, mutect2, varscan2
- ABCG2 | c.*1119C>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4875G>C | RNA (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- BAK1 | c.*903T>C | 3'UTR (SNP) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- BCO2 | c.*890A>G | 3'UTR (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- C9orf57 | c.*375G>A | 3'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as rs1016408899; called by muse, mutect2
- CADPS | c.1325+19531T>A | Intron (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- CALN1 | c.*8268del | 3'UTR (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel
- CNOT3 | c.*189C>T | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- CORIN | c.*1279T>A | 3'UTR (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- CXXC5 | c.*96C>G | 3'UTR (SNP) | VAF 34/344 reads (10%) | called by muse, mutect2
- DHCR24 | c.*2381G>C | 3'UTR (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- DMPK | c.1344+204G>A | Intron (SNP) | VAF 19/32 reads (59%) | called by mutect2, varscan2
- ETV1 | c.*638T>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- FLACC1 | c.*371A>C | 3'UTR (SNP) | VAF 11/28 reads (39%) | called by mutect2, varscan2
- FUNDC2P2 | n.72G>A | RNA (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- GGH | chr8:63038947 T>A | 5'Flank (SNP) | VAF 14/31 reads (45%) | called by muse, varscan2
- GGH | chr8:63038948 C>T | 5'Flank (SNP) | VAF 14/32 reads (44%) | called by muse, varscan2
- GNGT1 | c.97-24C>T | Intron (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- GPR173 | c.*2543G>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.256+82A>C | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- IL10RA | c.-62A>T | 5'UTR (SNP) | VAF 15/55 reads (27%) | called by mutect2, varscan2
- IL6R | c.*1154A>C | 3'UTR (SNP) | VAF 18/80 reads (23%) | catalogued as rs1445349536; called by muse, mutect2, varscan2
- INSYN1 | c.-404C>T | 5'UTR (SNP) | VAF 13/19 reads (68%) | catalogued as rs1436747766; called by muse, mutect2, varscan2
- KPNA5 | c.*45+2385T>A | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- LY6E | c.172+46C>A | Intron (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- MAP3K13 | c.*3043C>T | 3'UTR (SNP) | VAF 5/10 reads (50%) | catalogued as rs991725507; called by muse, mutect2
- MRAP2 | c.*176T>A | 3'UTR (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- PPP1R3C | c.*746T>C | 3'UTR (SNP) | VAF 5/86 reads (6%) | catalogued as rs1259031080; called by muse, mutect2
- RAB6C | c.*1147G>T | 3'UTR (SNP) | VAF 32/309 reads (10%) | catalogued as rs1409422398; called by muse, mutect2
- RAI14 | c.*1759T>G | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- RASGRP4 | chr19:38426207 G>C | 5'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- SLC25A37 | c.440-165C>T | Intron (SNP) | VAF 19/34 reads (56%) | catalogued as rs547659155; called by muse, mutect2, varscan2
- SYNM | c.*2304C>T | 3'UTR (SNP) | VAF 15/67 reads (22%) | catalogued as rs1043019278, COSV50443579; called by muse, mutect2, varscan2
- SYNRG | c.*910A>T | 3'UTR (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- TBC1D14 | c.844-6997G>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- TMC7 | c.*1032A>T | 3'UTR (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- TMEM9B | chr11:8964874 C>G | 5'Flank (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- TPRA1 | c.*62C>T | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- TRIP4 | c.1483+32C>G | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- UNC5D | c.*5482T>C | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- ZNF516 | c.*4004A>T | 3'UTR (SNP) | VAF 53/106 reads (50%) | called by muse, mutect2, varscan2
- ZNF516 | c.*1970G>T | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
